Somatic mutation profile of tumor specimen TCGA-21-5783-01A (aliquot TCGA-21-5783-01A-41D-2184-08) from TCGA case TCGA-21-5783, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.4 years (27,904 days).
Specimen TCGA-21-5783-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb50ec49-5f09-4bb0-9162-e9856a5110b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-5783-10A (Blood Derived Normal), aliquot TCGA-21-5783-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59cdbce6-b8dd-4dd7-b18c-34b2eb7a4eb1

The open-access MAF lists 459 somatic variants for this specimen: 337 protein-altering or splice-affecting, 110 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 285, Silent 110, Nonsense Mutation 28, Frame Shift Del 8, Splice Site 7, 3'UTR 4, Intron 4, Frame Shift Ins 3, In Frame Del 2, RNA 2, 5'UTR 2, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTK | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs128620183, CM940199, CM950170, COSV58117568, COSV58123749; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.329G>A p.W110* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | hotspot (GDC flag); catalogued as rs1057519852, COSV58682976, COSV58690849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 33/81 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs104894230, CM053284, CM081305, CM123157, COSV54236734, COSV54236774, COSV54238174; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs104894365, CM061082, COSV55501342, COSV55883432; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 41/103 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.1321G>A p.A441T (on ENST00000372530 / NM_001198934.2; = p.A398T on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV99767168; called by muse, mutect2, varscan2
- ACVR1B | c.1487A>G p.Q496R | Missense Mutation (SNP) | VAF 73/178 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.434); catalogued as COSV99231444; called by muse, mutect2, varscan2
- ADAMTS16 | c.3107C>A p.P1036H | Missense Mutation (SNP) | VAF 78/130 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99068535; called by muse, mutect2, varscan2
- ADAMTS6 | c.694C>A p.P232T | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV101125021; called by muse, mutect2, varscan2
- ADGRA2 | c.992C>A p.S331Y | Missense Mutation (SNP) | VAF 55/73 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100177856; called by muse, mutect2, varscan2
- ADGRV1 | c.10464G>T p.M3488I | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV101315805; called by muse, mutect2, varscan2
- ADH1B | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); catalogued as COSV100520738; called by muse, mutect2, varscan2
- ALDH1A2 | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 27/100 reads (27%) | catalogued as rs747754555, COSV99990668; called by muse, mutect2, varscan2
- ALOXE3 | c.1766C>T p.A589V | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100559683; called by muse, mutect2, varscan2
- ANKRD30A | c.511-1G>T p.X171_splice (on ENST00000611781; = p.X115_splice on NM_052997.2) | Splice Site (SNP) | VAF 55/100 reads (55%) | catalogued as COSV100652956, COSV64609404; called by muse, mutect2, varscan2
- ANKRD55 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 90/132 reads (68%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100591247; called by muse, mutect2, varscan2
- APBB1IP | c.1111A>G p.K371E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV100882016; called by muse, mutect2, varscan2
- ARF5 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 10/75 reads (13%) | catalogued as COSV99133706; called by muse, mutect2, varscan2
- ARFGEF1 | c.3577G>C p.D1193H | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99142079; called by muse, mutect2
- ARFGEF1 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); catalogued as COSV51609904, COSV99142081; called by muse, mutect2, varscan2
- ARFGEF3 | c.5817C>G p.I1939M | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.076); catalogued as COSV99293258; called by muse, mutect2, varscan2
- ARHGAP39 | c.3074C>G p.A1025G (on ENST00000276826 / NM_001308208.2; = p.A1056G on NM_025251.2) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV52773630, COSV99431074; called by muse, mutect2, varscan2
- ARHGEF26 | c.1817G>T p.C606F | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100726531; called by muse, mutect2, varscan2
- ATF6 | c.1543G>C p.E515Q | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.477); catalogued as COSV63408283, COSV63410119; called by muse, mutect2, varscan2
- ATL1 | c.1410G>C p.L470F | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.078); catalogued as COSV100613047; called by muse, mutect2, varscan2
- ATP10A | c.1474G>A p.V492M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.1); catalogued as COSV100791144; called by muse, mutect2, varscan2
- ATP2A2 | c.307A>G p.I103V | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs376143339; called by muse, mutect2, varscan2
- BCAP31 | c.259G>T p.G87W | Missense Mutation (SNP) | VAF 71/95 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100798924, COSV61451637; called by muse, mutect2, varscan2
- BIN2 | c.681G>A p.L227= | Splice Region (SNP) | VAF 31/144 reads (22%) | catalogued as COSV99909354; called by muse, mutect2, varscan2
- BIRC6 | c.12231G>C p.M4077I | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.341); catalogued as COSV101134337; called by muse, mutect2
- BTN2A1 | c.804G>T p.W268C | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100438526; called by muse, mutect2, varscan2
- BUD13 | c.1149C>G p.H383Q | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV99496425; called by muse, mutect2, varscan2
- C12orf40 | c.384+1G>A p.X128_splice | Splice Site (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100209995; called by muse, mutect2
- C12orf42 | c.1055G>A p.R352K | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.143); catalogued as COSV100172122; called by muse, mutect2, varscan2
- C2orf42 | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100033844; called by muse, mutect2, varscan2
- C6 | c.2720A>G p.K907R | Missense Mutation (SNP) | VAF 26/281 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99666976; called by muse, mutect2
- C9 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 25/276 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV99662002; called by muse, mutect2
- CAD | c.1087G>T p.G363W | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99254939; called by muse, mutect2, varscan2
- CARMIL1 | c.3185G>C p.R1062P | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100277600, COSV61521132; called by muse, mutect2, varscan2
- CAST | c.1789G>C p.E597Q (on ENST00000341926; = p.E680Q on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99700874; called by muse, mutect2, varscan2
- CBLN2 | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); catalogued as COSV54050746; called by muse, mutect2, varscan2
- CCDC88A | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99710300; called by muse, mutect2, varscan2
- CD1C | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.227); catalogued as rs1469611454, COSV63806278; called by muse, mutect2, varscan2
- CDCA2 | c.2480G>C p.R827T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV100398840; called by muse, mutect2, varscan2
- CDH11 | c.580A>C p.S194R | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99218104; called by muse, mutect2, varscan2
- CDH11 | c.425C>A p.P142Q | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV51758168, COSV99218106; called by muse, mutect2, varscan2
- CDH12 | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101202375, COSV101202896; called by muse, mutect2
- CEACAM5 | c.1537G>T p.V513L | Missense Mutation (SNP) | VAF 111/218 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV99703874; called by muse, mutect2, varscan2
- CEND1 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.104); catalogued as COSV100204183; called by muse, mutect2, varscan2
- CEP131 | c.3083G>A p.R1028H (on ENST00000269392 / NM_001319228.2; = p.R1025H on NM_014984.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs748288587, COSV99488147; called by muse, varscan2
- CFAP92 | c.753G>T p.Q251H | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99414723; called by muse, mutect2, varscan2
- CLDN17 | c.229C>A p.L77M | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99729137; called by muse, mutect2, varscan2
- CLVS1 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as rs1432471633, COSV100369866; called by muse, mutect2, varscan2
- CNTNAP2 | c.196A>T p.N66Y | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100665869; called by muse, mutect2, varscan2
- CNTNAP2 | c.1882T>C p.Y628H | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs770030792, COSV100665870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL11A2 | c.1304G>A p.G435E (on ENST00000341947 / NM_080680.3; = p.G328E on NM_080679.2) | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100553868; called by muse, mutect2, varscan2
- COPA | c.167G>A p.G56D | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749016135, COSV54104086; called by muse, mutect2, varscan2
- CPED1 | c.1741C>A p.P581T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1489114090, COSV100120569; called by muse, mutect2, varscan2
- CPLX4 | c.455C>G p.T152R | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1346133478, COSV100231369; called by muse, mutect2, varscan2
- CRTAP | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 40/57 reads (70%) | catalogued as COSV100310081; called by muse, mutect2, varscan2
- CSMD3 | c.7246+1G>A p.X2416_splice (on ENST00000297405 / NM_001363185.1; = p.X2312_splice on NM_052900.3) | Splice Site (SNP) | VAF 47/233 reads (20%) | catalogued as rs1326888419, COSV52179543, COSV99832578; called by muse, mutect2, varscan2
- CTTNBP2 | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.034); catalogued as COSV99353760; called by muse, mutect2, varscan2
- CYP19A1 | c.1405G>T p.E469* | Nonsense Mutation (SNP) | VAF 17/92 reads (18%) | catalogued as COSV99547639; called by muse, mutect2, varscan2
- CYP27A1 | c.1012G>C p.D338H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99298478, COSV99298483; called by muse, mutect2, varscan2
- DACH1 | c.1450A>G p.I484V (on ENST00000619232 / NM_001366712.1; = p.I432V on NM_080759.6) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV100498191; called by muse, mutect2, varscan2
- DCC | c.1204G>C p.A402P | Missense Mutation (SNP) | VAF 74/130 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100499605, COSV59128887; called by muse, mutect2, varscan2
- DCLK2 | c.1495T>A p.L499I | Missense Mutation (SNP) | VAF 92/199 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV99651909; called by muse, mutect2, varscan2
- DCUN1D2 | c.447G>C p.K149N | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as COSV100215175; called by muse, mutect2, varscan2
- DENND1B | c.122A>G p.D41G | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV99344294; called by muse, mutect2, varscan2
- DENND4A | c.3897A>C p.L1299F | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV101475320; called by muse, mutect2, varscan2
- DENND4C | c.5771A>G p.Y1924C (on ENST00000434457 / NM_001330640.2; = p.Y1875C on NM_017925.7) | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100194466; called by muse, mutect2, varscan2
- DENND5A | c.3727A>G p.I1243V | Missense Mutation (SNP) | VAF 67/94 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100064534; called by muse, mutect2, varscan2
- DGKQ | c.1363C>A p.H455N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.073); catalogued as COSV99892611; called by muse, varscan2
- DIAPH3 | c.3143G>A p.R1048H (on ENST00000400324 / NM_001042517.2; = p.R785H on NM_030932.3) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as rs775919583, COSV57380428, COSV99933144; called by muse, mutect2, varscan2
- DNAAF5 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV99859700; called by muse, mutect2, varscan2
- DNAH11 | c.11267G>T p.R3756L | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs554657293, COSV100179001; called by muse, mutect2, varscan2
- DNAH9 | c.7454C>A p.S2485* | Nonsense Mutation (SNP) | VAF 29/52 reads (56%) | catalogued as COSV52336455, COSV99305555; called by muse, mutect2, varscan2
- DNAJC13 | c.3105G>T p.Q1035H | Missense Mutation (SNP) | VAF 67/237 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV99607144; called by muse, mutect2, varscan2
- DOP1A | c.4936C>G p.R1646G | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1311042766, COSV52708677, COSV99381710; called by muse, mutect2, varscan2
- DPF3 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 40/95 reads (42%) | catalogued as COSV100818512; called by muse, mutect2, varscan2
- DPYSL3 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as rs374440794; called by muse, mutect2, varscan2
- DSG3 | c.1353C>A p.N451K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV99934070; called by muse, mutect2, varscan2
- DUOX2 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.104); catalogued as COSV101199718; called by muse, mutect2, varscan2
- DYNC1H1 | c.11938G>A p.A3980T | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.03); catalogued as COSV100794799; called by muse, mutect2, varscan2
- DYNC1I2 | c.1595G>T p.W532L | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV99783801; called by muse, mutect2
- DYNC2LI1 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs755856410, COSV53183264; called by muse, mutect2, varscan2
- DZANK1 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.94); catalogued as rs1199741103, COSV52756538; called by muse, mutect2, varscan2
- DZIP1 | c.2191G>T p.D731Y (on ENST00000347108; = p.D712Y on NM_014934.5) | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100714064; called by muse, mutect2, varscan2
- EFS | c.1009C>G p.L337V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV53734583; called by muse, mutect2, varscan2
- EIF5B | c.1900A>G p.I634V | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.14); catalogued as rs1013518881, COSV99177179; called by muse, mutect2
- ELF1 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT tolerated (0.65); PolyPhen benign (0.075); catalogued as COSV99523001; called by muse, mutect2, varscan2
- ENDOV | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV100108521; called by muse, mutect2, varscan2
- ENPEP | c.2762G>A p.G921E | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99487526; called by muse, mutect2, varscan2
- EPB41L3 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 52/77 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100548909; called by muse, mutect2, varscan2
- EPN1 | c.1181C>T p.A394V (on ENST00000270460 / NM_001321263.1; = p.A368V on NM_013333.3) | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99321830; called by muse, mutect2, varscan2
- EXO5 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as COSV99591266; called by muse, mutect2, varscan2
- EXOSC7 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.027); catalogued as COSV99651985; called by muse, mutect2, varscan2
- FAAH | c.1572G>T p.R524S | Missense Mutation (SNP) | VAF 51/68 reads (75%) | SIFT tolerated (0.07); PolyPhen benign (0.155); catalogued as COSV99680045; called by muse, mutect2, varscan2
- FAM117A | c.494C>G p.T165R | Missense Mutation (SNP) | VAF 82/143 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99544664, COSV99545120; called by muse, mutect2, varscan2
- FAM227B | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); catalogued as COSV100174908; called by muse, mutect2, varscan2
- FBL | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 14/64 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.019); catalogued as COSV99695263; called by muse, mutect2, varscan2
- FBXL13 | c.198C>A p.D66E | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs1167367491, COSV100500854, COSV100501496; called by muse, mutect2, varscan2
- FBXO7 | c.587A>G p.N196S | Missense Mutation (SNP) | VAF 117/216 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs548204763, COSV99832628; called by muse, mutect2, varscan2
- FBXW5 | c.1300A>G p.M434V | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as rs753006959, COSV99812457; called by muse, mutect2, varscan2
- FCRL3 | c.1270C>A p.L424M | Missense Mutation (SNP) | VAF 85/138 reads (62%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100943145; called by muse, mutect2, varscan2
- FERMT3 | c.1963G>A p.D655N (on ENST00000279227 / NM_178443.3; = p.D651N on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV99655794; called by muse, mutect2, varscan2
- FHL5 | c.739del p.S247Afs*19 | Frame Shift Del (DEL) | VAF 23/90 reads (26%) | catalogued as COSV100459030; called by mutect2, pindel, varscan2
- FLT1 | c.3374C>A p.S1125Y | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV56720280, COSV56727351, COSV99152556; called by muse, mutect2, varscan2
- FLYWCH1 | c.1654G>A p.A552T (on ENST00000253928 / NM_001308068.2; = p.A551T on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs762452782, COSV99558791; called by muse, varscan2
- FMNL2 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99979493; called by muse, mutect2, varscan2
- FNTB | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV99862875, COSV99863151; called by muse, mutect2, varscan2
- FOXJ2 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50825378; called by muse, mutect2, varscan2
- GADL1 | c.1231C>A p.R411S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as COSV99244274; called by muse, mutect2, varscan2
- GCC1 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs773918151, COSV100365507; called by muse, mutect2, varscan2
- GLYATL2 | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 65/120 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.144); catalogued as COSV99780344; called by muse, mutect2, varscan2
- GP5 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.137); catalogued as COSV55468515; called by muse, mutect2, varscan2
- GPCPD1 | c.812T>C p.I271T | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.214); catalogued as COSV100980157; called by muse, mutect2, varscan2
- GRIN1 | c.966G>C p.K322N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.704); catalogued as COSV100160186, COSV59298718; called by muse, mutect2, varscan2
- GSTO2 | c.609G>A p.W203* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | catalogued as COSV100086699; called by muse, mutect2, varscan2
- GSX1 | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 43/62 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100262530; called by muse, mutect2, varscan2
- GYPB | c.169G>T p.V57L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99301678; called by muse, mutect2
- HCN1 | c.514A>T p.T172S | Missense Mutation (SNP) | VAF 65/349 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100299974; called by muse, mutect2, varscan2
- HDAC7 | c.383C>T p.S128F (on ENST00000427332; = p.S167F on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs774438678, COSV50332624; called by muse, mutect2, varscan2
- HELZ | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62381682; called by muse, mutect2, varscan2
- HERC2 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 49/125 reads (39%) | catalogued as COSV99873122; called by muse, mutect2, varscan2
- HIVEP2 | c.4963A>T p.T1655S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as COSV99173181; called by muse, mutect2
- HNRNPH1 | c.1140_1142del p.F380del | In Frame Del (DEL) | VAF 17/96 reads (18%) | catalogued as rs1243081672; called by pindel, varscan2
- HOXB13 | c.649C>A p.R217S | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51704895, COSV99284849; called by muse, mutect2, varscan2
- HOXB4 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100203724; called by muse, mutect2, varscan2
- HOXB5 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as rs373035488; called by muse, mutect2, varscan2
- HS3ST5 | c.414G>A p.W138* | Nonsense Mutation (SNP) | VAF 20/101 reads (20%) | catalogued as COSV57143759; called by muse, mutect2, varscan2
- HUWE1 | c.6160G>T p.E2054* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as COSV99471860; called by muse, mutect2, varscan2
- IL23R | c.1651C>T p.L551F | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100724716; called by muse, mutect2, varscan2
- IMP4 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.065); catalogued as COSV99383698, COSV99383748; called by muse, mutect2
- IMPG2 | c.2333C>G p.P778R | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV51983295; called by muse, mutect2, varscan2
- INSR | c.1611-1G>A p.X537_splice | Splice Site (SNP) | VAF 4/23 reads (17%) | catalogued as CS141443, COSV100252057; called by muse, mutect2, varscan2
- ITGB3 | c.1911G>C p.K637N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101457578; called by muse, mutect2
- ITGB3 | c.2285G>A p.R762K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.92); PolyPhen benign (0.021); catalogued as rs760612810, COSV101457579; called by muse, mutect2, varscan2
- ITPK1 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50896533, COSV99968439; called by muse, mutect2, varscan2
- KALRN | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99563795; called by muse, mutect2, varscan2
- KCNH7 | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100035544; called by muse, mutect2, varscan2
- KCNT2 | c.13del p.E5Rfs*18 | Frame Shift Del (DEL) | VAF 30/71 reads (42%) | catalogued as COSV54063186; called by mutect2, pindel, varscan2
- KCNV1 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52085997, COSV99819491; called by muse, mutect2
- KHDRBS1 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.247); catalogued as COSV100306163; called by muse, mutect2, varscan2
- KIAA1586 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV100875341; called by muse, mutect2, varscan2
- KIF3B | c.1888G>T p.V630F | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV100996370; called by muse, mutect2, varscan2
- KIRREL3 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as rs367826386, COSV101585701; called by muse, varscan2
- KLF10 | c.1399C>G p.L467V | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99574727; called by muse, mutect2, varscan2
- KRT2 | c.1864G>T p.V622L | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV100548419; called by muse, mutect2, varscan2
- KRTAP26-1 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746309417, COSV100860412, COSV100860523; called by muse, mutect2, varscan2
- KTI12 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV65406204; called by muse, mutect2, varscan2
- LAMA2 | c.3466G>A p.D1156N | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs754256231, COSV101370399; called by muse, mutect2, varscan2
- LAMA3 | c.3283C>T p.Q1095* | Nonsense Mutation (SNP) | VAF 23/157 reads (15%) | catalogued as COSV100556588; called by muse, mutect2, varscan2
- LAMA5 | c.4238C>T p.P1413L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as COSV99439587; called by muse, mutect2, varscan2
- LAMC3 | c.634G>T p.G212C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100735966; called by muse, varscan2
- LILRA4 | c.1120C>A p.H374N | Missense Mutation (SNP) | VAF 73/313 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV99393072; called by muse, mutect2, varscan2
- LILRA4 | c.185A>T p.K62I | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99393073; called by muse, mutect2, varscan2
- LRBA | c.646-1G>T p.X216_splice | Splice Site (SNP) | VAF 4/37 reads (11%) | catalogued as CS160675, COSV100841436; called by muse, mutect2, varscan2
- LRRC23 | c.555G>C p.E185D | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV99145171, COSV99145395; called by muse, mutect2, varscan2
- LRRC45 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 35/97 reads (36%) | catalogued as rs1410089624, COSV100141799; called by muse, mutect2, varscan2
- LRRC7 | c.3565G>T p.G1189W (on ENST00000651989 / NM_001370785.2; = p.G1156W on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/103 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV50528238, COSV99066448; called by muse, mutect2, varscan2
- LRRCC1 | c.2209C>T p.Q737* | Nonsense Mutation (SNP) | VAF 49/132 reads (37%) | catalogued as COSV100835415, COSV100835574; called by muse, mutect2, varscan2
- MAGEE1 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as rs781879833, COSV100819378, COSV63910791; called by muse, mutect2, varscan2
- MAGEE2 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 31/42 reads (74%) | catalogued as COSV100973064; called by muse, mutect2, varscan2
- MAGI2 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100834277; called by muse, mutect2, varscan2
- MAP3K14 | c.2462G>A p.R821Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.553); catalogued as rs754282933, COSV59304644; called by muse, mutect2, varscan2
- MARCHF6 | c.1253G>T p.G418V | Missense Mutation (SNP) | VAF 189/293 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs774965742, COSV99929588; called by muse, mutect2, varscan2
- MBD6 | c.1129G>C p.E377Q | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100851644; called by muse, mutect2, varscan2
- MBIP | c.596C>A p.A199E | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100576773, COSV59253266; called by muse, mutect2, varscan2
- MERTK | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.099); catalogued as rs754922274, COSV99774535; called by muse, mutect2, varscan2
- MGST1 | c.144A>C p.E48D | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99163166; called by muse, mutect2, varscan2
- MIOS | c.2584G>T p.D862Y | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100402708; called by muse, mutect2, varscan2
- MIXL1 | c.383C>G p.S128C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100830812; called by muse, mutect2, varscan2
- MMP1 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 54/82 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV100187925; called by muse, mutect2, varscan2
- MOGS | c.2335C>T p.R779W | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs558187098, COSV99270479; called by muse, mutect2, varscan2
- MROH2B | c.1366A>T p.T456S | Missense Mutation (SNP) | VAF 72/108 reads (67%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.921); catalogued as COSV101270663, COSV68181178; called by muse, mutect2, varscan2
- MYH14 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.06); catalogued as rs373908919; called by muse, mutect2, varscan2
- MYH9 | c.5747C>T p.S1916F | Missense Mutation (SNP) | VAF 100/160 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV99338417; called by muse, mutect2, varscan2
- MYLK | c.1598T>C p.L533P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100658956; called by muse, mutect2, varscan2
- NAALAD2 | c.257T>A p.I86N | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100428382; called by muse, mutect2, varscan2
- NADK2 | c.421A>T p.R141W | Missense Mutation (SNP) | VAF 95/378 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99237432; called by muse, mutect2, varscan2
- NAV2 | c.5730G>C p.E1910D (on ENST00000396087 / NM_001244963.2; = p.E1851D on NM_145117.5) | Missense Mutation (SNP) | VAF 54/74 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1014467311, COSV100216743; called by muse, mutect2, varscan2
- NBEAL1 | c.7273G>C p.V2425L | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV101355477; called by muse, mutect2, varscan2
- NBPF1 | c.858G>A p.M286I | Missense Mutation (SNP) | VAF 44/572 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.356); catalogued as COSV101236428; called by muse, varscan2
- NDNF | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV101113157; called by muse, mutect2, varscan2
- NEIL3 | c.58C>A p.P20T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.186); catalogued as COSV99220335; called by muse, mutect2, varscan2
- NES | c.3829G>T p.E1277* | Nonsense Mutation (SNP) | VAF 90/119 reads (76%) | catalogued as COSV100957850; called by muse, mutect2, varscan2
- NME1-NME2 | c.859C>T p.H287Y (on ENST00000555572; = p.H262Y on NM_001018136.3) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1190810420, COSV100899932, COSV64510417; called by muse, mutect2, varscan2
- NSG2 | c.214-1G>C p.X72_splice | Splice Site (SNP) | VAF 31/51 reads (61%) | catalogued as COSV100292739, COSV100292784; called by muse, mutect2, varscan2
- NT5C1B | c.1799C>A p.A600E (on ENST00000359846 / NM_001199086.2; = p.A540E on NM_033253.4) | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV100409981; called by muse, mutect2, varscan2
- NT5C1B | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100409983; called by muse, mutect2, varscan2
- OLFM3 | c.568G>T p.E190* (on ENST00000338858 / NM_001288821.1; = p.E170* on NM_058170.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 37/53 reads (70%) | catalogued as COSV100129334, COSV58806239; called by muse, mutect2, varscan2
- OR2L2 | c.653del p.G218Afs*29 | Frame Shift Del (DEL) | VAF 80/142 reads (56%) | catalogued as COSV63554270; called by mutect2, pindel*, varscan2
- OR4A15 | c.723C>A p.H241Q | Missense Mutation (SNP) | VAF 90/152 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs774389659, COSV100123923; called by muse, mutect2, varscan2
- OR4C46 | c.756C>G p.C252W | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100060650; called by muse, mutect2, varscan2
- OR4K14 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV100520397, COSV59293010; called by muse, mutect2, varscan2
- OR51G2 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs766872582, COSV100432119; called by muse, mutect2, varscan2
- OR6C1 | c.725A>T p.H242L | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101110498; called by muse, mutect2, varscan2
- OR6N2 | c.909G>T p.R303S | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV100210101; called by muse, mutect2, varscan2
- PAPPA2 | c.4908G>C p.E1636D | Missense Mutation (SNP) | VAF 48/64 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1337360482, COSV100867958; called by muse, mutect2, varscan2
- PARD3B | c.1403G>T p.R468L | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs202130832, COSV100593218, COSV62535877; called by muse, mutect2, varscan2
- PASK | c.2641G>T p.G881W | Missense Mutation (SNP) | VAF 64/94 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99299307; called by muse, mutect2, varscan2
- PCDH18 | c.2668G>A p.D890N | Missense Mutation (SNP) | VAF 88/359 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.037); catalogued as COSV61267779; called by muse, mutect2, varscan2
- PCDHA3 | c.769A>T p.N257Y | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100973810; called by muse, mutect2, varscan2
- PCDHA6 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.41); catalogued as COSV100972243; called by muse, mutect2, varscan2
- PCDHB5 | c.2084C>T p.S695L | Missense Mutation (SNP) | VAF 85/171 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs781860324, COSV50647387; called by muse, mutect2, varscan2
- PCDHGB6 | c.763C>A p.L255M | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.457); catalogued as COSV99536800; called by muse, mutect2, varscan2
- PDE6A | c.1385A>G p.N462S | Missense Mutation (SNP) | VAF 55/95 reads (58%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV99678231; called by muse, mutect2, varscan2
- PDGFRA | c.1573C>A p.L525I | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99956439; called by muse, mutect2, varscan2
- PDHA2 | c.1005A>T p.E335D | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV99756824; called by muse, mutect2, varscan2
- PDZRN3 | c.2812G>T p.V938L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs780293470, COSV55209234, COSV99071462; called by muse, mutect2, varscan2
- PEAR1 | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT tolerated (0.74); PolyPhen benign (0.122); catalogued as COSV99441278; called by muse, mutect2, varscan2
- PHF13 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs752759806, COSV99275640; called by muse, mutect2, varscan2
- PIK3R4 | c.3427C>T p.L1143F | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as rs761293366, COSV100768360; called by muse, varscan2
- PKD1L1 | c.1768A>T p.K590* | Nonsense Mutation (SNP) | VAF 20/59 reads (34%) | catalogued as COSV56977068, COSV99219434; called by muse, mutect2, varscan2
- PLEKHA4 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as rs1389099566, COSV99612461; called by muse, mutect2, varscan2
- PLXDC2 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101024591; called by muse, mutect2, varscan2
- POLDIP3 | c.1070C>G p.S357* | Nonsense Mutation (SNP) | VAF 165/256 reads (64%) | catalogued as COSV99349046; called by muse, mutect2, varscan2
- PPIG | c.388C>G p.P130A | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.294); catalogued as COSV99644459; called by muse, mutect2
- PRKDC | c.10380A>T p.E3460D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV100040187; called by muse, mutect2
- PRORP | c.1738C>T p.H580Y | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.182); catalogued as COSV99155326; called by muse, mutect2, varscan2
- PRPF8 | c.4846C>T p.P1616S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100517413; called by muse, mutect2, varscan2
- PRSS1 | c.736A>G p.N246D | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV61190850; called by muse, mutect2
- PRTG | c.962T>C p.L321S | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV101221362; called by muse, mutect2, varscan2
- PSEN2 | c.41G>T p.C14F | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as COSV100423030; called by muse, mutect2, varscan2
- PTPN22 | c.1142T>C p.L381P (on ENST00000359785 / NM_001193431.2; = p.L326P on NM_012411.5) | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV100703574; called by muse, mutect2, varscan2
- PYROXD2 | c.1325T>A p.L442Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV100995957; called by muse, mutect2, varscan2
- R3HCC1L | c.748A>G p.M250V | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs376638744, COSV100107306; called by muse, mutect2, varscan2
- RABGGTA | c.1178G>T p.R393L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV52861794, COSV99252957; called by muse, mutect2, varscan2
- RANBP2 | c.8248G>T p.G2750W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV99311970; called by muse, mutect2
- RESF1 | c.2797G>C p.G933R | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.225); catalogued as COSV100440303, COSV100440392; called by muse, mutect2
- RIMS2 | c.4349A>G p.K1450R (on ENST00000666250 / NM_001348490.2; = p.K1021R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51650267; called by muse, mutect2, varscan2
- RIMS2 | c.4540C>A p.P1514T (on ENST00000666250 / NM_001348490.2; = p.P1085T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99167522; called by muse, varscan2
- RIMS2 | c.4541C>A p.P1514Q (on ENST00000666250 / NM_001348490.2; = p.P1085Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51676658; called by muse, mutect2, varscan2
- RNF148 | c.291G>T p.Q97H | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV100411585; called by muse, mutect2, varscan2
- RNF207 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV100933701, COSV100933787; called by muse, mutect2, varscan2
- RNF213 | c.9439C>T p.R3147C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781176178, COSV100300417; called by muse, mutect2, varscan2
- RNF38 | c.937G>C p.E313Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.731); catalogued as COSV99424974; called by muse, mutect2, varscan2
- RNF6 | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 36/119 reads (30%) | catalogued as COSV100644623; called by muse, mutect2, varscan2
- RSAD1 | c.725G>T p.R242L | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as COSV99364234; called by muse, mutect2, varscan2
- RTF2 | c.476C>T p.T159M | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); catalogued as rs1485450446, COSV99196482; called by muse, mutect2, varscan2
- RYR2 | c.8670G>T p.Q2890H | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.05); PolyPhen benign (0.196); catalogued as COSV63668579; called by muse, mutect2, varscan2
- RYR3 | c.1657G>T p.E553* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV101212605; called by muse, mutect2
- RYR3 | c.4291C>A p.L1431M | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.372); catalogued as COSV66811082; called by muse, mutect2, varscan2
- SALL2 | c.1874C>G p.S625* | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | catalogued as COSV58102790, COSV99046715; called by muse, mutect2, varscan2
- SALL3 | c.2213A>G p.Q738R | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101609984; called by muse, mutect2, varscan2
- SAV1 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 29/108 reads (27%) | catalogued as rs1206096807, COSV61205932; called by muse, mutect2, varscan2
- SCN9A | c.2764C>G p.R922G (on ENST00000303354; = p.R911G on NM_002977.3) | Missense Mutation (SNP) | VAF 104/294 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100312528, COSV57608654; called by muse, mutect2, varscan2
- SEC14L5 | c.2056G>T p.G686C | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV52039172, COSV99228812; called by muse, mutect2, varscan2
- SELP | c.2035A>G p.I679V | Missense Mutation (SNP) | VAF 356/527 reads (68%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99739690; called by muse, mutect2, varscan2
- SEMA5A | c.652A>G p.N218D | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as COSV101227968; called by muse, mutect2
- SLC12A9 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as rs747098043, COSV51937667; called by muse, mutect2, varscan2
- SLC35F1 | c.1227G>C p.*409Yext*8 | Nonstop Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV100837734; called by muse, varscan2
- SLC35G2 | c.1226C>G p.S409C | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101262014; called by muse, mutect2, varscan2
- SLC4A1AP | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as rs142838727; called by muse, mutect2, varscan2
- SLC9A2 | c.2258G>T p.R753I | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV99296198; called by muse, mutect2, varscan2
- SLITRK6 | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as COSV101233221; called by muse, mutect2, varscan2
- SNCA | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 27/152 reads (18%) | catalogued as COSV100409891; called by muse, mutect2, varscan2
- SORCS1 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs774753201, COSV99545766; called by muse, mutect2, varscan2
- SPATA6 | c.469A>G p.R157G | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.946); catalogued as COSV100893148; called by muse, mutect2, varscan2
- SPDEF | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754648678, COSV55062095; called by muse, mutect2, varscan2
- SPI1 | c.209T>A p.F70Y | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV99908850; called by muse, mutect2, varscan2
- SPON2 | c.206G>C p.W69S | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99335197; called by muse, mutect2, varscan2
- SPP1 | c.547G>C p.D183H (on ENST00000395080 / NM_001040058.2; = p.D169H on NM_000582.2) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs759100566, COSV99421022; called by muse, mutect2, varscan2
- SPPL2A | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as COSV99961536; called by muse, mutect2, varscan2
- STAG1 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs774614550, COSV52604457; called by muse, mutect2, varscan2
- STAMBP | c.1083G>T p.E361D | Missense Mutation (SNP) | VAF 100/436 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100277675, COSV59896937; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2471C>A p.P824Q | Missense Mutation (SNP) | VAF 73/120 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100561750, COSV100561773; called by muse, mutect2, varscan2
- STX7 | c.68A>G p.Q23R | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV100908436; called by muse, mutect2, varscan2
- SYTL5 | c.1841+1G>C p.X614_splice | Splice Site (SNP) | VAF 40/63 reads (63%) | catalogued as COSV99937156; called by muse, mutect2, varscan2
- TAF2 | c.3208A>G p.T1070A | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.931); catalogued as rs779111665, COSV100978640; called by muse, mutect2
- TAS2R46 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV101114664; called by muse, mutect2, varscan2
- TBC1D19 | c.733C>G p.Q245E | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs1417085850, COSV99336305; called by muse, mutect2, varscan2
- TCERG1 | c.3287C>G p.S1096* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | catalogued as COSV99694733; called by muse, mutect2, varscan2
- TEX15 | c.2008C>A p.Q670K (on ENST00000256246; = p.Q1053K on NM_001350162.2) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.155); catalogued as COSV99821242; called by muse, mutect2, varscan2
- TGM4 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99942266; called by muse, mutect2, varscan2
- TICAM1 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV50240729; called by muse, mutect2, varscan2
- TLE4 | c.1705A>C p.I569L | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV99511924; called by muse, mutect2, varscan2
- TMEM199 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as COSV99134763; called by muse, mutect2, varscan2
- TMPRSS11B | c.848C>T p.T283I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as COSV100219329; called by muse, mutect2, varscan2
- TNF | c.508C>T p.L170F | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV101403179; called by muse, mutect2, varscan2
- TNRC6B | c.334C>G p.P112A | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100109548; called by muse, mutect2, varscan2
- TPTE2 | c.1064G>A p.R355Q (on ENST00000400230 / NM_199254.2; = p.R278Q on NM_130785.3) | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs555497368, COSV55028143; called by muse, mutect2, varscan2
- TRIB3 | c.983A>G p.H328R | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs374473490; called by muse, mutect2, varscan2
- TRIP12 | c.5386C>G p.L1796V | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as COSV99390017; called by muse, mutect2, varscan2
- TTC16 | c.1608G>C p.L536F | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV100262883; called by muse, mutect2, varscan2
- TTN | c.76295C>A p.P25432H (on ENST00000591111; = p.P18008H on NM_003319.4) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | PolyPhen probably damaging (0.999); catalogued as COSV100589267, COSV100609943; called by muse, mutect2, varscan2
- TTN | c.21551C>A p.S7184Y (on ENST00000591111; = p.S6257Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | PolyPhen possibly damaging (0.816); catalogued as COSV100609945; called by muse, mutect2, varscan2
- TTN | c.2182G>C p.A728P (on ENST00000591111; = p.A682P on NM_003319.4) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | PolyPhen benign (0.186); catalogued as COSV100609946; called by muse, mutect2, varscan2
- UBD | c.172A>G p.K58E | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100589663; called by muse, mutect2, varscan2
- UGT2A3 | c.1101A>T p.K367N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99279795; called by muse, mutect2, varscan2
- UGT2A3 | c.629A>T p.K210I | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99279800; called by muse, mutect2, varscan2
- USF3 | c.301A>G p.K101E | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100325153; called by muse, mutect2, varscan2
- USH2A | c.6976G>A p.E2326K | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1449130784, COSV100233513, COSV56406248; called by muse, mutect2, varscan2
- USP7 | c.1673G>T p.R558L | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV100784157; called by muse, mutect2, varscan2
- USP7 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100784158; called by muse, mutect2, varscan2
- USP9X | c.6917G>A p.C2306Y | Missense Mutation (SNP) | VAF 60/95 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV100199024; called by muse, mutect2, varscan2
- VASN | c.1291T>G p.L431V | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV99227565; called by muse, mutect2, varscan2
- VPS13D | c.6236C>T p.S2079F | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1383045865, COSV99166300; called by muse, mutect2
- VPS50 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV99298080; called by muse, varscan2
- WBP11 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53761795; called by muse, mutect2, varscan2
- XRN1 | c.2443C>T p.R815C | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.339); catalogued as rs141258147; called by muse, mutect2, varscan2
- ZBTB2 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.979); catalogued as COSV100287601; called by muse, mutect2, varscan2
- ZBTB2 | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV100287603; called by muse, varscan2
- ZBTB2 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57313462; called by muse, varscan2
- ZBTB2 | c.454C>G p.P152A | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100287607; called by muse, mutect2, varscan2
- ZBTB2 | c.359C>G p.S120C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.343); catalogued as COSV100287611; called by muse, mutect2, varscan2
- ZC3H12B | c.1423C>A p.P475T | Missense Mutation (SNP) | VAF 80/110 reads (73%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as COSV59051856; called by muse, mutect2, varscan2
- ZDBF2 | c.3667C>A p.L1223I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.679); catalogued as COSV100984712; called by muse, mutect2, varscan2
- ZEB1 | c.116T>A p.L39Q | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100314254; called by muse, mutect2, varscan2
- ZFHX4 | c.2585G>T p.G862V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99261939; called by muse, mutect2
- ZFHX4 | c.6751C>A p.P2251T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51455010, COSV51491910; called by muse, mutect2
- ZHX3 | c.917T>C p.I306T | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV100475926; called by muse, mutect2, varscan2
- ZNF175 | c.2111C>T p.S704F | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99219445; called by muse, mutect2, varscan2
- ZNF408 | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 55/75 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV100305442; called by muse, mutect2, varscan2
- ZNF488 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.577); catalogued as rs1555213036; called by muse, mutect2, varscan2
- ZNF488 | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs782703463; called by muse, mutect2, varscan2
- ZNF517 | c.894C>G p.F298L | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100743604; called by muse, mutect2
- ZNF594 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV101280479; called by muse, mutect2, varscan2
- ZNF681 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 36/75 reads (48%) | catalogued as COSV101267450, COSV104432589; called by muse, mutect2, varscan2
- ZNF8 | c.841G>C p.G281R | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV52186615, COSV99544268; called by muse, mutect2, varscan2
- ZNF800 | c.1104T>G p.Y368* | Nonsense Mutation (SNP) | VAF 20/99 reads (20%) | catalogued as COSV56175620; called by muse, mutect2, varscan2
- ZNF813 | c.1145C>A p.P382H | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101124832; called by muse, mutect2, varscan2
- ZNF835 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs754377081, COSV101606326; called by muse, varscan2
- ZSCAN25 | c.1395G>C p.K465N | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99500527; called by muse, mutect2, varscan2
- ACACB | c.1049del p.G350Afs*23 | Frame Shift Del (DEL) | VAF 44/314 reads (14%) | called by mutect2, pindel*, varscan2
- CNGA2 | c.1461del p.I487Mfs*21 | Frame Shift Del (DEL) | VAF 63/115 reads (55%) | called by mutect2, pindel, varscan2
- CUX2 | c.3462del p.S1155Afs*9 | Frame Shift Del (DEL) | VAF 27/79 reads (34%) | called by mutect2, pindel, varscan2
- DCAF4 | c.848dup p.G284Wfs*15 | Frame Shift Ins (INS) | VAF 136/421 reads (32%) | called by mutect2, pindel, varscan2
- EBF2 | c.123del p.A42Rfs*20 | Frame Shift Del (DEL) | VAF 27/116 reads (23%) | called by mutect2, pindel, varscan2
- EMX2 | c.666dup p.Q223Tfs*10 | Frame Shift Ins (INS) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- FSIP1 | c.15G>T p.K5N | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- RHOXF1 | c.408dup p.A137Cfs*8 | Frame Shift Ins (INS) | VAF 90/169 reads (53%) | called by mutect2, pindel, varscan2
- TAF2 | c.609_615del p.K203Nfs*4 | Frame Shift Del (DEL) | VAF 23/107 reads (21%) | called by mutect2, pindel, varscan2
- TP53 | c.328_336del p.R110_G112del | In Frame Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- TRBV4-2 | c.147C>A p.N49K | Missense Mutation (SNP) | VAF 44/370 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- TRBV6-1 | c.287G>T p.R96M | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACTR3B | c.1062C>T p.S354= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs139229319, COSV55447790; called by muse, mutect2, varscan2
- ADGRB3 | c.4321C>T p.L1441= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV99484816; called by muse, mutect2, varscan2
- AKAP6 | c.1662T>A p.L554= | Silent (SNP) | VAF 47/109 reads (43%) | catalogued as COSV99800357; called by muse, mutect2, varscan2
- AKNAD1 | c.990C>A p.I330= | Silent (SNP) | VAF 116/197 reads (59%) | catalogued as COSV100645494; called by muse, mutect2, varscan2
- ANLN | c.1467A>T p.T489= | Silent (SNP) | VAF 88/201 reads (44%) | catalogued as COSV99732197; called by muse, mutect2, varscan2
- AP5M1 | c.828C>T p.D276= | Silent (SNP) | VAF 69/289 reads (24%) | catalogued as COSV99841190; called by muse, mutect2, varscan2
- ARMC3 | c.1968C>A p.P656= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99957944; called by muse, mutect2, varscan2
- ARRDC1 | c.321C>T p.I107= | Silent (SNP) | VAF 46/98 reads (47%) | catalogued as rs780827485, COSV101004519; called by muse, mutect2, varscan2
- ASF1B | c.267C>T p.A89= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs769600285, COSV99654270; called by muse, mutect2, varscan2
- ASPSCR1 | c.1524C>T p.D508= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV100142398; called by muse, mutect2, varscan2
- ATRNL1 | c.1755T>G p.S585= | Silent (SNP) | VAF 34/138 reads (25%) | catalogued as COSV100745127; called by muse, mutect2, varscan2
- BAZ2B | c.3255C>A p.L1085= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV54275525, COSV99680942; called by muse, mutect2
- BBOX1 | c.351C>A p.G117= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as COSV99589614; called by muse, mutect2
- BBS12 | c.210C>G p.L70= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as COSV100044914, COSV58562663; called by muse, mutect2, varscan2
- BEST3 | c.1071C>A p.P357= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV100437723; called by muse, mutect2, varscan2
- BPIFB3 | c.945G>C p.L315= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as rs138544042; called by muse, mutect2, varscan2
- C1QTNF12 | c.669G>A p.R223= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs745431486, COSV100382578; called by muse, varscan2
- C2orf42 | c.1026G>A p.S342= | Silent (SNP) | VAF 50/383 reads (13%) | catalogued as rs765921236, COSV100033845; called by muse, mutect2, varscan2
- CACNG6 | c.435A>T p.A145= | Silent (SNP) | VAF 62/351 reads (18%) | catalogued as COSV99403422; called by muse, mutect2, varscan2
- CDC42BPA | c.3948C>G p.T1316= (on ENST00000334218 / NM_001366019.2; = p.T1303= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs775505552, COSV100504809; called by muse, mutect2, varscan2
- CDON | c.1737C>G p.A579= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99701199; called by muse, varscan2
- CHD5 | c.3594G>A p.E1198= | Silent (SNP) | VAF 72/98 reads (73%) | catalogued as COSV99313434; called by muse, mutect2, varscan2
- CLPTM1L | c.717G>A p.V239= | Silent (SNP) | VAF 20/428 reads (5%) | catalogued as COSV100307044; called by muse, mutect2
- CLVS1 | c.63C>G p.A21= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV100369867, COSV57983890; called by muse, mutect2, varscan2
- CNGB3 | c.1287T>C p.S429= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV100181845; called by muse, mutect2, varscan2
- CNOT1 | c.3027C>T p.I1009= | Silent (SNP) | VAF 99/299 reads (33%) | catalogued as COSV99800027; called by muse, mutect2, varscan2
- COLEC12 | c.1107C>T p.T369= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV101232057; called by muse, mutect2, varscan2
- CSN1S1 | c.480T>G p.P160= | Silent (SNP) | VAF 121/279 reads (43%) | catalogued as COSV55889878, COSV99886693; called by muse, mutect2, varscan2
- CUX2 | c.903C>T p.A301= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as rs531467959, COSV55650191, COSV99919493; called by muse, mutect2, varscan2
- CYP11A1 | c.102T>A p.T34= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV51432933, COSV99165979; called by muse, mutect2, varscan2
- DMAC1 | c.210G>A p.R70= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV100830291; called by muse, mutect2, varscan2
- ELP5 | c.717C>T p.S239= | Silent (SNP) | VAF 49/124 reads (40%) | catalogued as rs772028750, COSV63040264; called by muse, mutect2, varscan2
- F13B | c.612C>A p.L204= | Silent (SNP) | VAF 63/187 reads (34%) | catalogued as COSV100803277; called by muse, mutect2, varscan2
- FGFRL1 | c.1149C>T p.I383= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV53258643; called by muse, mutect2, varscan2
- FOXF1 | c.156C>G p.S52= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV99296469; called by muse, mutect2, varscan2
- FRMD5 | c.225A>G p.T75= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as COSV101296439; called by muse, mutect2, varscan2
- GCNT3 | c.936C>T p.N312= | Silent (SNP) | VAF 85/187 reads (45%) | catalogued as rs775565320, COSV101251806; called by muse, mutect2, varscan2
- GOLGA8B | c.1632C>T p.T544= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs754888944, COSV99971860; called by muse, varscan2
- GPR161 | c.465G>A p.S155= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs751206783, COSV54792491; called by muse, mutect2, varscan2
- HAO1 | c.477G>C p.V159= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as COSV101113195, COSV101113244; called by muse, mutect2, varscan2
- HERC2 | c.13494G>T p.T4498= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV99873116; called by muse, mutect2, varscan2
- HIBADH | c.258A>G p.V86= | Silent (SNP) | VAF 45/140 reads (32%) | catalogued as COSV99607101; called by muse, mutect2, varscan2
- IGFBP1 | c.462C>A p.A154= | Silent (SNP) | VAF 57/140 reads (41%) | catalogued as COSV99298712; called by muse, mutect2, varscan2
- IGLV7-43 | c.72T>A p.T24= | Silent (SNP) | VAF 63/87 reads (72%) | called by muse, mutect2, varscan2
- ITGA2B | c.2074C>A p.R692= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs753533964, COSV52236521, COSV99288810; called by muse, varscan2
- JAZF1 | c.99C>A p.I33= | Silent (SNP) | VAF 26/113 reads (23%) | catalogued as COSV99386451; called by muse, mutect2, varscan2
- KANSL1 | c.393G>A p.L131= | Silent (SNP) | VAF 31/261 reads (12%) | catalogued as COSV99294425; called by muse, mutect2, varscan2
- KCNB2 | c.1581G>A p.T527= | Silent (SNP) | VAF 23/207 reads (11%) | catalogued as rs909418624, COSV73050592; called by muse, mutect2, varscan2
- KDM6B | c.66G>A p.L22= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV99641250; called by muse, mutect2, varscan2
- KLF14 | c.696C>T p.C232= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV60589006; called by muse, mutect2, varscan2
- LCE2D | c.69A>G p.K23= | Silent (SNP) | VAF 29/161 reads (18%) | catalogued as COSV100909538; called by muse, mutect2, varscan2
- LGI1 | c.858C>T p.C286= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV101004405; called by muse, mutect2, varscan2
- LRTM1 | c.447T>A p.T149= | Silent (SNP) | VAF 37/57 reads (65%) | catalogued as COSV99836009; called by muse, mutect2, varscan2
- MAGEC1 | c.2850C>T p.F950= | Silent (SNP) | VAF 76/110 reads (69%) | catalogued as rs761344832, COSV53576883, COSV99595529; called by muse, mutect2, varscan2
- MEX3B | c.1566C>T p.F522= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV61663286, COSV61664376; called by muse, mutect2, varscan2
- MRC2 | c.3081G>A p.L1027= | Silent (SNP) | VAF 128/275 reads (47%) | catalogued as rs1226301100, COSV57642076; called by muse, mutect2, varscan2
- NAA50 | c.261A>G p.G87= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as COSV99568609; called by muse, mutect2, varscan2
- NDST4 | c.2088C>T p.P696= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as COSV52122140; called by muse, mutect2, varscan2
- NDUFAF1 | c.372C>T p.V124= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as COSV52974801, COSV99531435; called by muse, mutect2, varscan2
- NPTX2 | c.1185C>T p.S395= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99674857; called by muse, mutect2, varscan2
- NRP2 | c.2169G>A p.T723= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as rs774103685, COSV55926130, COSV99783858; called by muse, mutect2, varscan2
- OR2T2 | c.258C>G p.L86= | Silent (SNP) | VAF 100/338 reads (30%) | catalogued as COSV61617826, COSV61618329; called by muse, mutect2, varscan2
- OR51A4 | c.165C>A p.P55= | Silent (SNP) | VAF 73/99 reads (74%) | catalogued as COSV100985223, COSV100985244; called by muse, mutect2, varscan2
- OVCH1 | c.333G>A p.Q111= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV58966188; called by muse, mutect2, varscan2
- PARP11 | c.288C>T p.L96= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs745349560, COSV99958954; called by muse, mutect2, varscan2
- PAX2 | c.1188T>C p.Y396= (on ENST00000428433 / NM_003987.5; = p.Y373= on NM_000278.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV100695146; called by muse, mutect2, varscan2
- PCDHA8 | c.1452G>T p.A484= | Silent (SNP) | VAF 59/93 reads (63%) | catalogued as COSV100969429, COSV65324193; called by muse, mutect2, varscan2
- PEG3 | c.4737C>T p.L1579= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs143583223; called by muse, mutect2, varscan2
- PIN4 | c.33A>G p.V11= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV99512407; called by muse, mutect2, varscan2
- PKHD1 | c.7299T>C p.D2433= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100582790; called by muse, mutect2, varscan2
- PLA2G4F | c.1842A>T p.P614= | Silent (SNP) | VAF 35/63 reads (56%) | catalogued as rs1187126183, COSV99300596; called by muse, mutect2, varscan2
- PMS1 | c.1923G>A p.Q641= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as COSV100575610, COSV100575778; called by muse, mutect2, varscan2
- PPM1N | c.858G>A p.A286= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV99838903; called by muse, mutect2, varscan2
- PPP6R2 | c.2316G>C p.P772= (on ENST00000216061 / NM_001365836.1; = p.P745= on NM_014678.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV53297898, COSV99324153; called by muse, mutect2, varscan2
- PRKG1 | c.741G>A p.K247= | Silent (SNP) | VAF 38/128 reads (30%) | catalogued as COSV100908316; called by muse, mutect2, varscan2
- PRSS8 | c.474C>A p.A158= | Silent (SNP) | VAF 82/185 reads (44%) | catalogued as COSV99571395; called by muse, mutect2, varscan2
- PTPRJ | c.1950C>T p.D650= | Silent (SNP) | VAF 28/140 reads (20%) | catalogued as rs763072219, COSV101394961; called by muse, mutect2, varscan2
- RRBP1 | c.1818G>A p.Q606= (on ENST00000377813 / NM_001365613.2; = p.X177_splice on NM_004587.3) | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV99853902; called by muse, mutect2, varscan2
- SEMG1 | c.1143A>T p.L381= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV99725217; called by muse, mutect2, varscan2
- SHROOM4 | c.3156A>T p.P1052= | Silent (SNP) | VAF 21/30 reads (70%) | catalogued as COSV99173345; called by muse, mutect2, varscan2
- SLC2A11 | c.939G>A p.A313= (on ENST00000345044 / NM_001024938.4; = p.A320= on NM_030807.5) | Silent (SNP) | VAF 38/52 reads (73%) | catalogued as rs185026065; called by muse, mutect2, varscan2
- SLC32A1 | c.1170G>A p.A390= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs780915973, COSV99462122, COSV99462568; called by muse, mutect2, varscan2
- SLC35F4 | c.1449C>T p.F483= (on ENST00000339762 / NM_001352015.2; = p.F447= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV100333787; called by muse, mutect2, varscan2
- SLC4A3 | c.1095G>T p.S365= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99812762; called by muse, mutect2
- SOX21 | c.195C>A p.R65= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV100977909; called by muse, mutect2, varscan2
- SPHKAP | c.4290G>A p.Q1430= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100763760, COSV100764074; called by muse, mutect2, varscan2
- SPSB1 | c.255C>T p.D85= | Silent (SNP) | VAF 101/251 reads (40%) | catalogued as rs199970373, COSV100049407; called by muse, mutect2, varscan2
- STAB1 | c.126A>G p.V42= | Silent (SNP) | VAF 81/141 reads (57%) | catalogued as COSV100401629; called by muse, mutect2, varscan2
- STARD13 | c.891C>G p.S297= (on ENST00000336934 / NM_001243476.3; = p.S179= on NM_052851.3) | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV99715775; called by muse, mutect2, varscan2
- SYNE1 | c.3621G>C p.L1207= (on ENST00000367255 / NM_182961.4; = p.L1214= on NM_033071.3) | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV99561905; called by muse, mutect2
- TAAR5 | c.855G>T p.L285= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as COSV99236878; called by muse, mutect2
- TGM7 | c.978G>T p.L326= | Silent (SNP) | VAF 35/231 reads (15%) | catalogued as COSV101476848; called by muse, mutect2, varscan2
- TRAT1 | c.354G>A p.K118= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as COSV99849223; called by muse, mutect2, varscan2
- TRIM27 | c.981C>T p.P327= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV101019309; called by muse, mutect2, varscan2
- TRPM3 | c.339T>C p.N113= (on ENST00000357533 / NM_001366142.2; = p.N82= on NM_001007471.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/95 reads (57%) | catalogued as COSV100624556; called by muse, mutect2, varscan2
- TRPM4 | c.1521G>C p.L507= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV99419653; called by muse, mutect2, varscan2
- TTN | c.79494C>G p.S26498= (on ENST00000591111; = p.S19074= on NM_003319.4) | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs1316956131, COSV100609940; called by muse, mutect2, varscan2
- UFSP2 | c.1101G>A p.T367= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs755002032, COSV52990961; called by muse, mutect2, varscan2
- USP37 | c.1824A>G p.A608= | Silent (SNP) | VAF 62/136 reads (46%) | catalogued as COSV99294356; called by muse, varscan2
- VN1R4 | c.381T>A p.V127= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100237409; called by muse, mutect2
- VPS50 | c.924A>G p.Q308= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV99298090; called by muse, varscan2
- VWA7 | c.1608C>T p.I536= | Silent (SNP) | VAF 85/344 reads (25%) | catalogued as rs1307433317, COSV100991816; called by muse, mutect2, varscan2
- WASHC4 | c.675A>G p.K225= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs1226695901, COSV100162393; called by muse, mutect2
- ZCWPW1 | c.1884C>T p.S628= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as rs372286297; called by muse, mutect2, varscan2
- ZFHX3 | c.6045C>T p.L2015= | Silent (SNP) | VAF 40/289 reads (14%) | catalogued as rs760092834, COSV99198576; called by muse, mutect2, varscan2
- ZIC1 | c.153C>A p.P51= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV99291842; called by muse, mutect2, varscan2
- ZIC1 | c.711C>T p.N237= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99291844; called by muse, mutect2, varscan2
- ZIC1 | c.993C>A p.P331= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as COSV51552002; called by muse, mutect2, varscan2
- ZNF230 | c.648A>G p.R216= | Silent (SNP) | VAF 62/108 reads (57%) | catalogued as rs1323510285, COSV101431985; called by muse, mutect2, varscan2
- ZNF251 | c.1512C>G p.L504= | Silent (SNP) | VAF 32/222 reads (14%) | catalogued as COSV99478422; called by muse, mutect2, varscan2
- ATAD3B | c.*201C>G | 3'UTR (SNP) | VAF 37/87 reads (43%) | catalogued as COSV100426411; called by muse, mutect2, varscan2
- C15orf65 | c.19-167G>A | Intron (SNP) | VAF 4/12 reads (33%) | catalogued as rs753094976, COSV101041228; called by muse, varscan2
- CACNG7 | c.*1G>T | 3'UTR (SNP) | VAF 87/228 reads (38%) | catalogued as rs761346839, COSV99711979; called by muse, mutect2, varscan2
- ELP5 | c.-2T>A | 5'UTR (SNP) | VAF 3/24 reads (13%) | catalogued as COSV100020989; called by muse, mutect2
- MIR517A | n.84G>C | RNA (SNP) | VAF 28/119 reads (24%) | called by muse, mutect2, varscan2
- OR51E1 | c.*1G>A | 3'UTR (SNP) | VAF 59/85 reads (69%) | catalogued as COSV101211494; called by muse, mutect2, varscan2
- PPP3CA | c.*1C>T | 3'UTR (SNP) | VAF 32/133 reads (24%) | catalogued as COSV100547580; called by muse, mutect2, varscan2
- RBM44 | c.-98-2580G>T | Intron (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100389801; called by muse, mutect2
- RPL4 | c.283-117A>G | Intron (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100328590; called by muse, mutect2, varscan2
- SSPOP | n.13425del | RNA (DEL) | VAF 17/87 reads (20%) | called by mutect2, pindel, varscan2
- STAU2 | c.-29C>T | 5'UTR (SNP) | VAF 26/197 reads (13%) | catalogued as COSV100708792; called by muse, mutect2, varscan2
- TP53AIP1 | c.141+180G>T | Intron (SNP) | VAF 11/22 reads (50%) | catalogued as COSV101513095; called by muse, mutect2, varscan2
